Gene-level copy-number profile of tumor specimen TCGA-OR-A5LL-01A from TCGA case TCGA-OR-A5LL, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 75.6 years (27,607 days).
Specimen TCGA-OR-A5LL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.fe311303-e123-4ebb-a729-3a52fa9e7b1e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5LL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9e8ac851-536c-437d-b855-ec80fadf529f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,561; copy number 2: 3,723; copy number 3: 11,947; copy number 4: 36,745; copy number 5: 2,851; copy number 6: 1,459; copy number 7: 340; copy number 8: 162; copy number 9: 21; copy number 10: 31; copy number 11: 190; copy number 12: 42; copy number 13: 44; copy number 14: 94; copy number 15: 50; copy number 16: 178; copy number 18: 62; copy number 19: 19; copy number 22: 63; copy number 23: 217; copy number 26: 5; copy number 28: 10; copy number 37: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5LL-01A-11D-A29H-01): tumor purity 0.77, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,030 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–153,226,006, 414 genes, copy number 11–18 (broad region; genes not listed).
- chr1:153,728,050–155,087,538, 78 genes, copy number 23 (within-gene range 2–23) (broad region; genes not listed).
- chr1:158,127,287–162,446,566, 197 genes, copy number 15–23 (broad region; genes not listed).
- chr2:15,564,170–17,817,798, 37 genes, copy number 15–22 (within-gene range 2–22): AC008278.2, DDX1, AC008278.1, LINC01804, AC113608.1, RNU5E-7P, RPLP1P5, AC010145.2, MYCNOS, MYCNUT, MYCN, RN7SL104P, AC010145.1, GACAT3, AC130710.1, AC174048.1, AC142283.1, AC010745.1, AC010745.2, AC010745.3, AC010745.5, AC010745.4, AC010880.1, AC104623.1, AC104623.2, CYRIA, AC008164.1, AC008069.1, LINC01866, RN7SKP168, ZFYVE9P2, PSMC1P10, RAD51AP2, VSNL1, SMC6, GEN1, MSGN1.
- chr2:79,185,231–80,648,861, 1 gene, copy number 28 (within-gene range 2–28): CTNNA2.
- chr2:79,492,704–86,808,396, 113 genes, copy number 12–37 (broad region; genes not listed).
- chr5:767,382–1,345,099, 21 genes, copy number 9 (within-gene range 3–9): BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L.
- chr5:121,363,002–128,083,172, 94 genes, copy number 14 (within-gene range 8–14) (broad region; genes not listed).
- chr5:128,538,013–130,598,779, 17 genes, copy number 10–16 (within-gene range 8–16): SLC27A6, AC008588.1, ISOC1, MIR4633, AC008679.1, MIR4460, ADAMTS19-AS1, ADAMTS19, AC008591.1, MINAR2, CHSY3, RNU6ATAC10P, RNA5SP191, HSPA8P4, RNU7-53P, ARL2BPP4, AC005741.1.
- chr5:132,556,019–133,224,413, 31 genes, copy number 13 (within-gene range 7–13): RAD50, TH2LCRR, IL13, IL4, AC004039.1, KIF3A, CCNI2, SEPTIN8, SOWAHA, AC004775.1, SHROOM1, RNA5SP192, GDF9, UQCRQ, LEAP2, AFF4, AC010240.2, Y_RNA, ATP6V0E1P1, AC010240.3, AC010240.1, Y_RNA, ZCCHC10, AC113410.1, AC113410.5, AC113410.4, HSPA4, AC113410.3, AC113410.2, AC010307.2, AC010307.1.
- chr5:133,243,764–133,275,977, 2 genes, copy number 13: AC010307.3, AC010307.4.
- chr12:85,567,878–87,170,429, 10 genes, copy number 11: AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1, AC010196.1, AC079597.1, RPL23AP68.
- chr12:114,504,876–114,898,529, 11 genes, copy number 10: RN7SKP216, AC069240.1, OSTF1P1, AC010177.1, Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1, AC026765.2, AC009804.2.
- chr16:70,802,084–71,230,722, 4 genes, copy number 10 (within-gene range 4–10): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.

Autosomal genes at a single copy (total copy number 1): 1,561. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
